Gene-level copy-number profile of tumor specimen C3N-01405-01 from CPTAC case C3N-01405, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 59.2 years (21,609 days).
Specimen C3N-01405-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7b63714b-187e-4afe-a756-f4db4d3e0427.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01405-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,748 have no estimate.
https://portal.gdc.cancer.gov/files/05bb36df-c715-449e-afc6-39a840108232

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 360; copy number 1: 3,489; copy number 2: 23,352; copy number 3: 18,072; copy number 4: 9,329; copy number 5: 1,288; copy number 6: 2,564; copy number 7: 249; copy number 9: 15; copy number 10: 10; copy number 11: 91; copy number 13: 55; copy number 14: 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:8,603,547–8,603,984, 1 gene: RPSAP68.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,273 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,903,318–169,630,193, 759 genes, copy number 6–9 (broad region; genes not listed).
- chr4:54,836,041–55,125,595, 8 genes, copy number 6: AC097494.1, LINC02358, AC111194.1, RPL38P3, RNU6-410P, AC111194.2, RN7SL424P, KDR.
- chr5:58,198–45,696,498, 676 genes, copy number 6–7 (within-gene range 3–7) (broad region; genes not listed).
- chr8:56,776,283–145,066,685, 1,332 genes, copy number 6 (broad region; genes not listed).
- chr9:66,253,424–72,008,136, 86 genes, copy number 5 (broad region; genes not listed).
- chr10:2,501,600–75,431,588, 1,199 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr11:65,367,438–65,538,704, 18 genes, copy number 6 (within-gene range 3–6): AP000944.1, SLC25A45, FRMD8, NEAT1, AP000944.4, AP000944.3, AP000944.2, MIR612, AP000769.4, AP000769.1, LINC02736, AP000769.6, MALAT1, AP000769.2, AP000769.5, AP000769.3, SNRPGP19, SCYL1.
- chr11:133,783,671–135,075,908, 29 genes, copy number 6: LINC02743, SPATA19, AP001979.1, IGSF9B, MIR4697, LINC02730, LINC02731, AP000911.1, JAM3, PTP4A2P2, NCAPD3, AP001775.1, AP001775.2, VPS26B, THYN1, ACAD8, GLB1L3, AP000859.1, GLB1L2, B3GAT1, B3GAT1-DT, AP004550.1, AP001999.1, LINC02706, LINC02714, AP003062.2, LINC02697, AP003062.1, LINC02684.
- chr14:30,734,926–36,658,801, 122 genes, copy number 9–14 (within-gene range 3–14) (broad region; genes not listed).
- chr14:42,807,378–46,651,781, 41 genes, copy number 9–11: YWHAQP1, AL163153.1, TUBBP3, HNRNPUP1, KRT8P2, AL358913.1, ARHGAP16P, LINC02307, EIF4BP1, AL109766.1, YWHAZP1, AL161752.1, LINC02277, FSCB, AL356022.1, LINC02302, DOCK11P1, AL049870.2, AL049870.1, RRAGAP1, C14orf28, AL049870.3, KLHL28, TOGARAM1, AL121809.2, AL121809.1, PRPF39, SNORD58, SNORD127, FKBP3, FANCM, MIS18BP1, RNU6-552P, DNAJC19P9, AL162632.3, AL162632.1, AL162632.2, AL139354.1, LINC02303, LINC00871, RPL10L.
- chr21:12,999,676–13,067,033, 3 genes, copy number 5: AP001464.1, ANKRD30BP2, RNU6-614P.

Autosomal genes at a single copy (total copy number 1): 1,008. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
